Somatic mutation profile of tumor specimen TCGA-KK-A8ID-01A (aliquot TCGA-KK-A8ID-01A-11D-A364-08) from TCGA case TCGA-KK-A8ID, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 70.8 years (25,851 days).
Specimen TCGA-KK-A8ID-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96fa38d5-5754-4e5e-8d07-f6ac7b75bd63.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A8ID-11A (Solid Tissue Normal), aliquot TCGA-KK-A8ID-11A-12D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3667bd5-81eb-4355-9fc1-120e29b69dc5

The open-access MAF lists 56 somatic variants for this specimen: 36 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 17, Frame Shift Del 4, Intron 2, In Frame Del 2, 5'UTR 1, Nonsense Mutation 1, Frame Shift Ins 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TTN | c.56008C>T p.R18670* (on ENST00000591111; = p.R11246* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 75/137 reads (55%) | catalogued as rs869312055, CM1514595, COSV59955046; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANKK1 | c.603G>T p.K201N | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV100392958; called by muse, varscan2
- BCL11B | c.719C>A p.A240E (on ENST00000357195 / NM_001282237.2; = p.A169E on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1239069309, COSV100595703; called by muse, varscan2
- CAMTA1 | c.2170A>T p.N724Y | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.34); catalogued as COSV100351526; called by muse, mutect2, varscan2
- CCDC28B | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.645); catalogued as COSV99356719; called by muse, mutect2, varscan2
- CDK12 | c.2320G>A p.E774K | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1297511599, COSV101420502; called by muse, mutect2, varscan2
- CHRDL1 | c.429G>A p.E143= (on ENST00000372045; = p.E149= on NM_145234.4) | Splice Region (SNP) | VAF 22/28 reads (79%) | catalogued as rs1317164825, COSV99488439; called by muse, mutect2, varscan2
- CPS1 | c.2919C>G p.D973E | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV99241381, COSV99243569; called by muse, mutect2, varscan2
- CRYL1 | c.515C>A p.T172N | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV53416021, COSV53420525; called by muse, mutect2, varscan2
- CTSO | c.268T>G p.S90A | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV101467868; called by muse, mutect2, varscan2
- ECE1 | c.2092C>G p.L698V | Missense Mutation (SNP) | VAF 10/264 reads (4%) | SIFT tolerated (0.69); PolyPhen benign (0.1); catalogued as COSV99942103; called by muse, mutect2
- FAM122A | c.448C>G p.R150G | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99599351; called by muse, mutect2, varscan2
- GPBP1L1 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 65/141 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs1370250809, COSV99322567; called by muse, mutect2, varscan2
- KIF6 | c.517A>G p.T173A | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.336); catalogued as rs1053373394, COSV99759702; called by muse, mutect2, varscan2
- MCTP1 | c.2759C>A p.A920D | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100387689; called by muse, mutect2, varscan2
- NOTCH4 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.72); catalogued as rs1183058401, COSV66681710; called by muse, mutect2
- NXF1 | c.608A>T p.E203V | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV99586227; called by muse, mutect2, varscan2
- PAX3 | c.947C>A p.S316Y | Missense Mutation (SNP) | VAF 83/284 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs763098498, COSV100399902; called by muse, mutect2, varscan2
- PPP6R2 | c.1744A>G p.N582D (on ENST00000216061 / NM_001365836.1; = p.N555D on NM_014678.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as COSV99324525; called by muse, mutect2, varscan2
- ROBO4 | c.2854C>A p.P952T | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs781384984, COSV100127741; called by muse, mutect2, varscan2
- RPL10A | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.367); catalogued as COSV100003463; called by muse, mutect2, varscan2
- SETBP1 | c.2882T>G p.I961S | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99954110; called by muse, mutect2, varscan2
- SLC25A23 | c.268G>C p.D90H | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99902443; called by muse, mutect2, varscan2
- SNTG1 | c.142G>A p.G48S | Missense Mutation (SNP) | VAF 64/164 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV99384874; called by muse, mutect2, varscan2
- TLCD3B | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99662514; called by muse, mutect2
- WASF3 | c.1130C>T p.S377F | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.05); catalogued as rs372445710; called by muse, mutect2, varscan2
- XPO7 | c.578C>A p.S193Y | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1299119573, COSV99381684; called by muse, mutect2
- XYLT1 | c.1120G>A p.V374I | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV99762605; called by muse, mutect2
- ARFGEF1 | c.70_73del p.E24* | Frame Shift Del (DEL) | VAF 34/75 reads (45%) | called by mutect2, pindel, varscan2
- CCDC113 | c.844_870del p.K282_K290del | In Frame Del (DEL) | VAF 36/113 reads (32%) | called by mutect2, pindel
- CDC27 | c.520_536del p.Q174Sfs*11 | Frame Shift Del (DEL) | VAF 12/55 reads (22%) | called by mutect2, pindel, varscan2
- CDK12 | c.3008_3009del p.L1003Rfs*3 | Frame Shift Del (DEL) | VAF 49/149 reads (33%) | called by mutect2, pindel, varscan2
- EXT1 | c.1066_1078del p.V356Sfs*12 | Frame Shift Del (DEL) | VAF 10/41 reads (24%) | called by mutect2, pindel, varscan2
- FMN2 | c.1182_1184del p.A395del | In Frame Del (DEL) | VAF 14/35 reads (40%) | called by mutect2, pindel
- GAD2 | c.1460dup p.N487Kfs*6 | Frame Shift Ins (INS) | VAF 11/107 reads (10%) | called by mutect2, pindel, varscan2
- GCOM1 | c.1014_1023del p.X338_splice | Splice Site (DEL) | VAF 6/19 reads (32%) | called by mutect2, varscan2
- DHPS | c.477G>T p.R159= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as COSV99269670; called by muse, mutect2, varscan2
- GABRB1 | c.816T>G p.S272= | Silent (SNP) | VAF 38/112 reads (34%) | catalogued as COSV99782529; called by muse, mutect2, varscan2
- GABRG1 | c.423A>G p.G141= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV99778450; called by muse, mutect2, varscan2
- GPATCH3 | c.438T>A p.P146= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV100658862; called by muse, varscan2
- HIPK2 | c.75C>T p.F25= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV100702382; called by muse, mutect2, varscan2
- KCNB1 | c.1236C>T p.I412= | Silent (SNP) | VAF 88/146 reads (60%) | catalogued as rs777806517, COSV65569418; called by muse, mutect2, varscan2
- KHDC4 | c.1296T>A p.A432= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as COSV100850833; called by muse, varscan2
- KIF1A | c.2622C>T p.S874= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs556611351, COSV100241776; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLPP7 | c.297C>T p.C99= | Silent (SNP) | VAF 50/112 reads (45%) | catalogued as rs1225442530, COSV64836115; called by muse, mutect2, varscan2
- PTBP1 | c.192G>T p.R64= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV100608889, COSV62459031; called by muse, mutect2, varscan2
- SCN11A | c.3135G>T p.L1045= | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as rs1283244121, COSV100182009, COSV100182165; called by muse, mutect2, varscan2
- SRGAP1 | c.1890G>A p.V630= | Silent (SNP) | VAF 54/131 reads (41%) | catalogued as COSV100754924; called by muse, mutect2, varscan2
- SSBP2 | c.312A>C p.L104= | Silent (SNP) | VAF 71/146 reads (49%) | catalogued as COSV100283882; called by muse, mutect2, varscan2
- TMPRSS9 | c.1248C>A p.S416= (on ENST00000648592; = p.S382= on NM_182973.2) | Silent (SNP) | VAF 25/50 reads (50%) | catalogued as COSV100211542; called by muse, mutect2, varscan2
- TMTC2 | c.2100C>T p.F700= | Silent (SNP) | VAF 36/103 reads (35%) | catalogued as COSV100338448; called by muse, mutect2, varscan2
- TRIM10 | c.868C>T p.L290= | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as COSV100939761; called by muse, mutect2, varscan2
- UBE3A | c.1737G>A p.V579= | Silent (SNP) | VAF 37/70 reads (53%) | catalogued as rs749731066, COSV99217567; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- KIF1B | c.2115+7262dup | Intron (INS) | VAF 26/56 reads (46%) | called by mutect2, varscan2
- KIF1B | c.2115+7263delinsAC | Intron (INS) | VAF 23/71 reads (32%) | called by mutect2*, pindel, varscan2*
- LCE2C | c.-2G>A | 5'UTR (SNP) | VAF 50/131 reads (38%) | catalogued as COSV100909457; called by muse, mutect2, varscan2
